Somatic mutation profile of tumor specimen 0DU3LM from CCDI case PBCKEJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.3 years (4,483 days).
Specimen 0DU3LM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fba9b6f-95f2-44f6-9f56-1c5235874dca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b888eac3-c5da-411a-ae09-fdd3a479ddfc

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUP35 | c.203T>C p.L68S | Missense Mutation (SNP) | VAF 60/1319 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs770534252; called by muse, mutect2
- TGFB2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 41/850 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.343); catalogued as COSV65108950; called by muse, mutect2
- DCAF10 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 48/1794 reads (3%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); called by muse, mutect2
- MRC2 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 118/2596 reads (5%) | called by muse, mutect2
- ZIC3 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
